Somatic mutation profile of tumor specimen TCGA-D9-A1JX-06A (aliquot TCGA-D9-A1JX-06A-11D-A19A-08) from TCGA case TCGA-D9-A1JX, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS.
Specimen TCGA-D9-A1JX-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3af7eded-b4ae-4470-91bb-c62f1c787144.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D9-A1JX-10A (Blood Derived Normal), aliquot TCGA-D9-A1JX-10A-01D-A19A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e6151f4-ec8b-4b8c-8676-00e1084f9db5

The open-access MAF lists 210 somatic variants for this specimen: 138 protein-altering or splice-affecting, 63 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 128, Silent 63, Nonsense Mutation 7, Intron 6, 3'UTR 2, Frame Shift Ins 2, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ACTL7B | c.682G>C p.D228H | Missense Mutation (SNP) | VAF 38/48 reads (79%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as COSV65927425; called by muse, mutect2, varscan2
- ADAMTS14 | c.2009G>A p.R670H | Missense Mutation (SNP) | VAF 31/37 reads (84%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.534); catalogued as rs374207153; called by muse, mutect2, varscan2
- ADAMTS18 | c.1768G>A p.G590S | Missense Mutation (SNP) | VAF 77/209 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1314087753, COSV51412727; called by muse, mutect2, varscan2
- ADGRE5 | c.967C>T p.R323W (on ENST00000242786 / NM_078481.4; = p.R230W on NM_001784.5) | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs758365972, COSV54411116; called by muse, mutect2
- ADH1B | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 122/364 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.787); catalogued as COSV59294987; called by muse, mutect2
- AMFR | c.323G>C p.G108A | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as COSV51921627; called by muse, varscan2
- ARHGAP29 | c.2621T>C p.L874S | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as COSV53112340; called by muse, mutect2, varscan2
- ASTN2 | c.3934A>G p.S1312G (on ENST00000313400 / NM_001365069.1; = p.S1261G on NM_014010.5) | Missense Mutation (SNP) | VAF 26/33 reads (79%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV56005476; called by muse, mutect2, varscan2
- ASTN2 | c.1331C>T p.S444F (on ENST00000313400 / NM_001365069.1; = p.S393F on NM_014010.5) | Missense Mutation (SNP) | VAF 34/43 reads (79%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs866109686, COSV57764562; called by muse, mutect2, varscan2
- ATP2B2 | c.1784G>A p.R595H (on ENST00000352432; = p.R561H on NM_001683.5) | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768463609, COSV59497269; called by muse, mutect2, varscan2
- B4GAT1 | c.662A>G p.N221S | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT tolerated (0.92); PolyPhen benign (0.006); catalogued as COSV60820173; called by muse, mutect2, varscan2
- BAZ2B | c.4757C>T p.P1586L | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as COSV100600875, COSV58601510; called by muse, mutect2, varscan2
- BBS2 | c.1343C>T p.P448L | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV55326669; called by muse, mutect2, varscan2
- BRD3 | c.71dup p.E25Gfs*51 | Frame Shift Ins (INS) | VAF 20/32 reads (63%) | catalogued as rs763134487; called by mutect2, varscan2
- BRINP1 | c.2098C>T p.R700W | Missense Mutation (SNP) | VAF 82/111 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs541291613, COSV56291761, COSV99774028; called by muse, mutect2, varscan2
- C1orf94 | c.1658A>G p.N553S (on ENST00000488417 / NM_001134734.2; = p.N363S on NM_032884.5) | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as COSV64913530; called by muse, mutect2, varscan2
- C6 | c.2743G>T p.G915* | Nonsense Mutation (SNP) | VAF 34/92 reads (37%) | catalogued as COSV54710859, COSV99667776; called by muse, mutect2, varscan2
- CARMIL1 | c.3610G>A p.E1204K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.169); catalogued as COSV61517923; called by muse, mutect2
- CASR | c.2530G>A p.E844K (on ENST00000490131; = p.E921K on NM_000388.4) | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as rs755629322, COSV56136433; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDHR5 | c.1233G>A p.M411I | Missense Mutation (SNP) | VAF 34/53 reads (64%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.797); catalogued as COSV57643228; called by muse, mutect2, varscan2
- CEMIP | c.1041G>A p.W347* | Nonsense Mutation (SNP) | VAF 29/63 reads (46%) | catalogued as COSV54993221; called by muse, mutect2, varscan2
- CEP170B | c.4447G>T p.V1483L (on ENST00000453495; = p.V1412L on NM_015005.3) | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.607); catalogued as rs780681011, COSV52044788; called by muse, mutect2, varscan2
- CFAP57 | c.529T>C p.F177L | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV65264509; called by muse, mutect2, varscan2
- CFAP91 | c.2044G>A p.E682K | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56341282; called by muse, mutect2, varscan2
- CHL1 | c.1841C>T p.P614L (on ENST00000397491 / NM_001253387.1; = p.P630L on NM_006614.4) | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs772990615, COSV56594382; called by muse, mutect2, varscan2
- CIDEA | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 37/56 reads (66%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs753389170, COSV57598616; called by muse, mutect2, varscan2
- COL11A1 | c.3587C>T p.P1196L | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV62184532; called by muse, mutect2, varscan2
- COL22A1 | c.2551C>T p.P851S | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747566535, COSV57338522; called by muse, mutect2, varscan2
- COL9A3 | c.803G>A p.G268D | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.834); catalogued as rs771415281, COSV59653019; called by muse, mutect2, varscan2
- CYP4F3 | c.398G>A p.G133E | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55410288; called by muse, mutect2, varscan2
- CYP4Z1 | c.1190C>T p.S397F | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as COSV61965066; called by muse, mutect2, varscan2
- DNAH11 | c.6739A>C p.N2247H | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV60957551; called by muse, mutect2, varscan2
- DNAH11 | c.7726G>A p.D2576N | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs1282090941, COSV60957558; called by muse, mutect2, varscan2
- DTX4 | c.400G>A p.V134I | Missense Mutation (SNP) | VAF 40/69 reads (58%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs200498275; called by muse, mutect2, varscan2
- DYSF | c.5454G>A p.W1818* | Nonsense Mutation (SNP) | VAF 7/19 reads (37%) | catalogued as COSV99249263; called by muse, mutect2, varscan2
- ELAPOR2 | c.2816C>T p.A939V (on ENST00000450689 / NM_001142749.3; = p.A772V on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV51887223; called by muse, mutect2, varscan2
- ELOVL6 | c.152T>G p.M51R | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV56429190; called by muse, mutect2, varscan2
- ESRRA | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV50005605; called by muse, mutect2, varscan2
- FAM170A | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 53/68 reads (78%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV58925354; called by muse, mutect2, varscan2
- FAT4 | c.7016C>T p.S2339L | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs373528845, COSV58690983; called by muse, mutect2, varscan2
- FBXL20 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.224); catalogued as rs1433521578, COSV52897329; called by muse, mutect2, varscan2
- FNIP2 | c.953C>T p.S318F | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV52440343; called by muse, mutect2, varscan2
- FOXS1 | c.812C>T p.S271L | Missense Mutation (SNP) | VAF 31/45 reads (69%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV54066368; called by muse, mutect2, varscan2
- FZR1 | c.252C>A p.N84K | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs374041533, COSV58051926; called by muse, mutect2, varscan2
- GPLD1 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.028); catalogued as rs762586465, COSV57757554; called by muse, mutect2, varscan2
- GRM7 | c.649G>A p.G217S | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV63144893, COSV63157411; called by muse, mutect2, varscan2
- GSPT1 | c.1465G>A p.G489R (on ENST00000420576 / NM_001130007.2; = p.G627R on NM_002094.4) | Missense Mutation (SNP) | VAF 51/146 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70452684; called by muse, mutect2, varscan2
- GUCA1C | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 57/146 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.204); catalogued as rs1265768088, COSV51712957; called by muse, mutect2, varscan2
- HEPH | c.2646T>A p.Y882* (on ENST00000343002; = p.Y615* on NM_014799.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 28/55 reads (51%) | catalogued as COSV57964508; called by muse, mutect2, varscan2
- HNF4G | c.1136C>T p.P379L (on ENST00000354370 / NM_001330561.2; = p.P426L on NM_004133.5) | Missense Mutation (SNP) | VAF 53/117 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.703); catalogued as COSV62968950; called by muse, mutect2, varscan2
- HRC | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as COSV99418162; called by muse, mutect2, varscan2
- HSD3B2 | c.526G>A p.G176S | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV65593261, COSV65593941; called by muse, mutect2, varscan2
- IL1B | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs775562734, COSV54521186; called by muse, mutect2, varscan2
- IL21R | c.1396G>A p.G466S | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.81); PolyPhen benign (0.005); catalogued as COSV61970637; called by muse, mutect2, varscan2
- IL27RA | c.1162C>T p.P388S | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54600999; called by muse, mutect2, varscan2
- INO80 | c.2596C>T p.P866S | Missense Mutation (SNP) | VAF 53/141 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as COSV100732118, COSV62738497; called by muse, mutect2, varscan2
- INPP4A | c.770A>T p.H257L | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as COSV99304677; called by muse, mutect2, varscan2
- ISLR | c.398A>G p.E133G | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); catalogued as COSV51433956; called by muse, mutect2, varscan2
- ISY1-RAB43 | c.783G>A p.M261I | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.219); catalogued as COSV56440697; called by muse, mutect2, varscan2
- KCNJ12 | c.1253G>A p.G418D | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV59167194, COSV59168634; called by muse, mutect2, varscan2
- KCNJ3 | c.857G>A p.R286Q | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.02); catalogued as rs369917007; called by muse, mutect2, varscan2
- KIF2B | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52128682, COSV52130189; called by muse, mutect2, varscan2
- KRTAP4-3 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.404); catalogued as rs1331915843, COSV66940718; called by muse, mutect2, varscan2
- LILRA1 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52181217; called by muse, varscan2
- MAP2K3 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 42/265 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV57561722, COSV57565499; called by muse, mutect2, varscan2
- MARCHF4 | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); catalogued as COSV56105221; called by muse, mutect2, varscan2
- MEGF10 | c.3148G>A p.E1050K | Missense Mutation (SNP) | VAF 52/75 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57249717; called by muse, mutect2, varscan2
- MGRN1 | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1014474091, COSV52150181; called by muse, mutect2, varscan2
- MRM2 | c.223C>T p.R75W | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); catalogued as rs138541422; called by muse, varscan2
- MROH1 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58189773; called by muse, mutect2, varscan2
- MTERF3 | c.286C>T p.Q96* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as rs1311949862, COSV54632856; called by mutect2, varscan2
- MTR | c.3208G>C p.E1070Q | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.818); catalogued as COSV63965034, COSV63965336; called by muse, mutect2
- MUC16 | c.30670C>T p.P10224S | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.246); catalogued as COSV67467155; called by muse, mutect2, varscan2
- MUC16 | c.26387C>A p.A8796E | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.943); catalogued as COSV67468896; called by muse, mutect2, varscan2
- MUC16 | c.176C>T p.S59F | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.541); catalogued as rs1335142801, COSV67468902; called by muse, mutect2, varscan2
- MYO18B | c.7628C>T p.P2543L | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV59135414; called by muse, mutect2, varscan2
- NCKAP5 | c.1232G>A p.R411Q | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.036); catalogued as rs772472479, COSV58436593, COSV58444914; called by muse, mutect2, varscan2
- NFKBIL1 | c.541A>G p.M181V | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV65990449; called by muse, mutect2, varscan2
- NPAP1 | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV61507459; called by muse, mutect2, varscan2
- NR3C2 | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.229); catalogued as COSV60991443; called by muse, mutect2, varscan2
- NSL1 | c.605C>T p.S202F | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.231); catalogued as COSV65329163; called by muse, mutect2, varscan2
- OLFM3 | c.454G>A p.E152K (on ENST00000338858 / NM_001288821.1; = p.E132K on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as rs373338533, COSV58805324; called by muse, mutect2, varscan2
- OR1M1 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.071); catalogued as rs765053649, COSV70036933; called by muse, mutect2, varscan2
- OR2T8 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 24/217 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs149611352; called by muse, mutect2, varscan2
- OR4K2 | c.319T>A p.F107I | Missense Mutation (SNP) | VAF 41/145 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.066); catalogued as COSV53849585; called by muse, mutect2, varscan2
- OR52L1 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.703); catalogued as rs982635202, COSV59986572; called by muse, mutect2, varscan2
- OR6A2 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as rs151066337; called by muse, mutect2, varscan2
- OR6C1 | c.793A>G p.R265G | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.104); catalogued as rs1565662391, COSV65573508; called by muse, mutect2, varscan2
- PCDHGA2 | c.1640C>T p.S547L | Missense Mutation (SNP) | VAF 61/90 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV53955710; called by muse, mutect2, varscan2
- PCLO | c.3547G>A p.E1183K | Missense Mutation (SNP) | VAF 84/150 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.194); catalogued as COSV61617434; called by muse, mutect2, varscan2
- PIK3R6 | c.1954G>A p.E652K | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as COSV61003416; called by muse, mutect2, varscan2
- PLA2R1 | c.1279A>G p.T427A | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.257); catalogued as COSV51779289; called by muse, mutect2, varscan2
- POM121L12 | c.360G>A p.M120I | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.141); catalogued as COSV68693043; called by muse, mutect2, varscan2
- POU5F1 | c.482G>A p.G161E | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52563836; called by muse, mutect2, varscan2
- PPP1R9A | c.2951C>T p.A984V | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.541); catalogued as COSV56894601; called by muse, mutect2, varscan2
- PRKACB | c.999A>T p.E333D | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.745); catalogued as rs1234775485, COSV65763110; called by muse, mutect2, varscan2
- PSMB1 | c.256C>T p.H86Y | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT tolerated (1); PolyPhen probably damaging (0.989); catalogued as COSV51530682; called by muse, mutect2, varscan2
- PTPRK | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 49/74 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs868427142, COSV63894383; called by muse, mutect2, varscan2
- RADIL | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.106); catalogued as rs767492216, COSV68201080; called by muse, mutect2, varscan2
- RARB | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs756703369; called by muse, mutect2, varscan2
- RASGRF1 | c.311A>C p.Q104P | Missense Mutation (SNP) | VAF 78/193 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69179272; called by muse, mutect2, varscan2
- RBCK1 | c.1361T>C p.V454A (on ENST00000356286 / NM_031229.4; = p.V412A on NM_006462.6) | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.202); catalogued as COSV62292308; called by muse, mutect2, varscan2
- RGS7 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 257/361 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as COSV100471887, COSV58541016; called by muse, mutect2, varscan2
- RPH3AL | c.351G>A p.K117= | Splice Region (SNP) | VAF 7/20 reads (35%) | catalogued as COSV58742731; called by muse, mutect2, varscan2
- SCN1A | c.1754G>A p.G585E | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.771); catalogued as COSV57671564; called by muse, mutect2, varscan2
- SESTD1 | c.515C>T p.S172L | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.527); catalogued as COSV58931407; called by muse, mutect2
- SETD5 | c.3779C>T p.S1260F | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV56711357; called by muse, mutect2, varscan2
- SIGLEC8 | c.744G>A p.W248* | Nonsense Mutation (SNP) | VAF 46/97 reads (47%) | catalogued as COSV58473828; called by muse, mutect2, varscan2
- SIRPB1 | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 76/135 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV53538943; called by muse, mutect2, varscan2
- SLC2A13 | c.1891C>T p.R631W | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs141841078, COSV55113490; called by muse, mutect2, varscan2
- SLC9A4 | c.1739G>A p.G580E | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV54834252; called by muse, mutect2, varscan2
- SLIT3 | c.3220G>A p.D1074N | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT tolerated (0.72); PolyPhen benign (0.02); catalogued as rs556673057, COSV60610114; called by muse, mutect2, varscan2
- SP140 | c.255T>A p.F85L | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.122); catalogued as COSV59450260; called by muse, mutect2, varscan2
- SPEF2 | c.3910G>A p.E1304K | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.019); catalogued as COSV61544772, COSV61548574; called by muse, mutect2, varscan2
- SPHKAP | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 78/206 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.084); catalogued as rs868542240, COSV60869806, COSV60876282; called by muse, mutect2, varscan2
- SSTR5 | c.919C>T p.L307F | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as COSV53512318; called by muse, mutect2, varscan2
- STPG4 | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV54278769; called by muse, mutect2
- TAB3 | c.2032C>T p.R678* | Nonsense Mutation (SNP) | VAF 16/25 reads (64%) | catalogued as COSV55837209; called by muse, mutect2, varscan2
- TCOF1 | c.3322C>T p.P1108S (on ENST00000377797 / NM_001135243.1; = p.P1031S on NM_000356.4) | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT tolerated (0.1); PolyPhen benign (0.177); catalogued as COSV60348935; called by muse, mutect2, varscan2
- TLL1 | c.988A>G p.T330A | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.975); catalogued as COSV50285096; called by muse, mutect2, varscan2
- TMEM108 | c.656T>C p.I219T | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.246); catalogued as COSV58872553; called by muse, mutect2, varscan2
- TNFSF10 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200301971, COSV53843411, COSV53843679; called by muse, mutect2, varscan2
- TNFSF15 | c.273C>A p.D91E | Missense Mutation (SNP) | VAF 30/35 reads (86%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV65010373, COSV65010919; called by muse, mutect2, varscan2
- TRIP4 | c.833G>C p.R278P | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV56031103; called by muse, mutect2, varscan2
- TRRAP | c.3986T>G p.V1329G | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.276); catalogued as COSV62845164; called by muse, mutect2, varscan2
- TTC29 | c.641G>A p.G214E | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV57272956; called by muse, mutect2
- TTN | c.12289C>T p.L4097F (on ENST00000591111; = p.L4051F on NM_003319.4) | Missense Mutation (SNP) | VAF 35/104 reads (34%) | catalogued as COSV59922373; called by muse, mutect2, varscan2
- TTN | c.1132G>C p.G378R | Missense Mutation (SNP) | VAF 27/71 reads (38%) | PolyPhen possibly damaging (0.803); catalogued as COSV60088521; called by muse, mutect2, varscan2
- TUBE1 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); catalogued as rs1554316100, COSV100898285, COSV64087947; called by muse, mutect2, varscan2
- ZFHX4 | c.8581G>A p.D2861N | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.329); catalogued as rs367746294; called by muse, varscan2
- ZFHX4 | c.8681A>T p.D2894V | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs751611821, COSV50853386; called by muse, varscan2
- ZFPM2 | c.2749G>A p.E917K | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.757); catalogued as COSV65873876, COSV65876100; called by muse, mutect2, varscan2
- ZNF423 | c.3271G>C p.D1091H (on ENST00000563137 / NM_001379286.1; = p.D1083H on NM_015069.4) | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV104388201, COSV52189937; called by muse, mutect2, varscan2
- ZNF490 | c.1334C>T p.P445L | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV61008154; called by muse, mutect2, varscan2
- ZNF667 | c.739C>T p.H247Y | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.368); catalogued as COSV52632981, COSV52634876; called by muse, mutect2, varscan2
- CPEB2 | c.2121dup p.K708* | Frame Shift Ins (INS) | VAF 10/40 reads (25%) | called by mutect2, pindel, varscan2
- GPR179 | c.3566G>A p.G1189E (on ENST00000621958; = p.G1188E on NM_001004334.4) | Missense Mutation (SNP) | VAF 98/239 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- ABCB5 | c.1731C>T p.I577= (on ENST00000404938 / NM_001163941.2; = p.I132= on NM_178559.6) | Silent (SNP) | VAF 37/73 reads (51%) | catalogued as rs149931729; called by muse, mutect2, varscan2
- ANKS3 | c.702G>A p.R234= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as COSV58509114; called by muse, mutect2, varscan2
- BPIFB1 | c.1389G>A p.L463= | Silent (SNP) | VAF 27/96 reads (28%) | catalogued as COSV53606735; called by muse, mutect2, varscan2
- BRD8 | c.1419C>T p.L473= (on ENST00000254900 / NM_139199.2; = p.L546= on NM_006696.4) | Silent (SNP) | VAF 39/65 reads (60%) | catalogued as COSV50149840; called by muse, mutect2, varscan2
- CCDC170 | c.1794G>A p.E598= | Silent (SNP) | VAF 55/83 reads (66%) | catalogued as COSV53341203; called by muse, mutect2, varscan2
- CCDC51 | c.756G>T p.A252= | Silent (SNP) | VAF 42/103 reads (41%) | catalogued as COSV56490124; called by muse, mutect2, varscan2
- CDHR2 | c.3024C>T p.L1008= | Silent (SNP) | VAF 49/67 reads (73%) | catalogued as rs1293508410, COSV56139385; called by muse, mutect2, varscan2
- CDK11A | c.1848C>T p.F616= (on ENST00000378633 / NM_001313896.2; = p.F613= on NM_024011.4) | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as rs201004006, COSV52307419; called by muse, mutect2, varscan2
- CNTN4 | c.1587C>T p.I529= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as rs753950086, COSV61868231; called by muse, varscan2
- CRLF2 | c.468C>T p.F156= | Silent (SNP) | VAF 23/37 reads (62%) | catalogued as rs755785714, COSV67493750; called by muse, mutect2, varscan2
- CYP4A11 | c.325C>T p.L109= | Silent (SNP) | VAF 37/104 reads (36%) | catalogued as COSV60223824; called by muse, mutect2, varscan2
- DIRAS1 | c.81C>T p.F27= | Silent (SNP) | VAF 25/49 reads (51%) | catalogued as rs762064600, COSV60215445; called by muse, mutect2, varscan2
- DNAAF3 | c.1146C>T p.L382= (on ENST00000524407 / NM_001256715.2; = p.L429= on NM_178837.4) | Silent (SNP) | VAF 36/103 reads (35%) | catalogued as COSV61277318; called by muse, mutect2, varscan2
- EIF6 | c.540C>T p.P180= | Silent (SNP) | VAF 69/315 reads (22%) | catalogued as COSV55770288; called by muse, mutect2, varscan2
- ELANE | c.495C>T p.I165= | Silent (SNP) | VAF 30/102 reads (29%) | catalogued as rs200923638, COSV55048181; called by muse, mutect2, varscan2
- EPHA1 | c.1059A>G p.E353= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV51971679; called by muse, mutect2, varscan2
- EPHA6 | c.1449C>T p.I483= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV67573852; called by muse, mutect2, varscan2
- ESPL1 | c.6198C>T p.D2066= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as COSV54476038; called by muse, mutect2, varscan2
- FAT1 | c.4371T>A p.S1457= | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as COSV71674330; called by muse, mutect2, varscan2
- FRAS1 | c.1761G>A p.G587= | Silent (SNP) | VAF 27/75 reads (36%) | catalogued as COSV53613530; called by muse, mutect2, varscan2
- FREM1 | c.1344C>T p.V448= | Silent (SNP) | VAF 11/13 reads (85%) | catalogued as rs537788336, COSV63087332; called by muse, mutect2, varscan2
- GJA8 | c.636G>C p.V212= | Silent (SNP) | VAF 31/90 reads (34%) | catalogued as COSV53789023; called by muse, mutect2, varscan2
- HRC | c.1464G>A p.K488= | Silent (SNP) | VAF 40/98 reads (41%) | catalogued as COSV99418167; called by muse, mutect2, varscan2
- HSPG2 | c.3276C>T p.S1092= | Silent (SNP) | VAF 48/103 reads (47%) | catalogued as COSV65972074; called by muse, mutect2, varscan2
- INPP4A | c.771C>T p.H257= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as rs781432748, COSV50794788; called by muse, mutect2, varscan2
- IRX2 | c.519G>A p.K173= | Silent (SNP) | VAF 44/124 reads (35%) | catalogued as COSV57411392; called by muse, mutect2, varscan2
- ITGAE | c.960C>T p.L320= | Silent (SNP) | VAF 85/253 reads (34%) | catalogued as rs758204504, COSV53992176, COSV53994623; called by muse, mutect2, varscan2
- ITIH5 | c.591C>T p.I197= | Silent (SNP) | VAF 72/92 reads (78%) | catalogued as rs369114884, COSV56904119, COSV56912641; called by muse, mutect2, varscan2
- KRT28 | c.873G>A p.Q291= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as COSV60685250; called by muse, mutect2, varscan2
- MAGEE2 | c.294C>T p.F98= | Silent (SNP) | VAF 21/35 reads (60%) | catalogued as COSV64897507; called by muse, mutect2, varscan2
- MAP3K9 | c.2694C>T p.P898= (on ENST00000554752 / NM_001284230.1; = p.P912= on NM_033141.4) | Silent (SNP) | VAF 64/175 reads (37%) | catalogued as COSV67121483; called by muse, mutect2, varscan2
- MARCHF10 | c.1719G>A p.V573= | Silent (SNP) | VAF 66/145 reads (46%) | catalogued as rs1191600815, COSV60887489; called by muse, mutect2, varscan2
- MN1 | c.3747G>A p.E1249= | Silent (SNP) | VAF 57/200 reads (29%) | catalogued as rs774045773, COSV56558616; called by muse, mutect2, varscan2
- MYO1F | c.2784G>A p.K928= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs773206689, COSV100596591, COSV57795521; called by muse, mutect2, varscan2
- MYOCD | c.2757C>T p.F919= | Silent (SNP) | VAF 23/54 reads (43%) | catalogued as rs200336311, COSV58503952; called by muse, mutect2, varscan2
- NAA11 | c.72G>A p.E24= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as COSV54513824, COSV54514662; called by muse, mutect2, varscan2
- NMRK2 | c.525C>T p.S175= | Silent (SNP) | VAF 30/80 reads (38%) | catalogued as COSV51455513; called by muse, mutect2, varscan2
- NOL6 | c.1413C>T p.D471= | Silent (SNP) | VAF 95/126 reads (75%) | catalogued as COSV53042115; called by muse, mutect2, varscan2
- OCA2 | c.1014C>T p.L338= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as rs142591701; called by muse, mutect2, varscan2
- OR2F1 | c.88C>T p.L30= | Silent (SNP) | VAF 136/256 reads (53%) | catalogued as rs369902208; called by muse, mutect2, varscan2
- OR6C3 | c.935G>A p.*312= | Silent (SNP) | VAF 14/28 reads (50%) | catalogued as COSV65571227; called by muse, mutect2, varscan2
- P2RY6 | c.843G>A p.A281= | Silent (SNP) | VAF 28/36 reads (78%) | catalogued as rs371644059; called by muse, mutect2, varscan2
- PARP10 | c.456G>A p.E152= | Silent (SNP) | VAF 39/126 reads (31%) | catalogued as COSV57297943; called by muse, mutect2, varscan2
- PCLO | c.15198G>A p.K5066= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV61637597; called by muse, varscan2
- PLEKHG2 | c.537C>T p.F179= | Silent (SNP) | VAF 37/85 reads (44%) | catalogued as rs1428215208, COSV52677681; called by muse, mutect2, varscan2
- PROX1 | c.609T>C p.S203= | Silent (SNP) | VAF 62/98 reads (63%) | catalogued as COSV54779393; called by muse, mutect2, varscan2
- PRSS38 | c.324C>T p.I108= | Silent (SNP) | VAF 15/106 reads (14%) | catalogued as COSV64540535; called by muse, mutect2, varscan2
- RBM47 | c.342C>T p.A114= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as COSV55935656; called by muse, varscan2
- REM2 | c.388C>T p.L130= | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as COSV57465574; called by muse, mutect2, varscan2
- RFNG | c.774C>T p.F258= | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as COSV57649210; called by muse, mutect2
- ROR2 | c.1179G>A p.S393= | Silent (SNP) | VAF 23/40 reads (58%) | catalogued as rs541919641, COSV65218014; called by muse, mutect2, varscan2
- SCN3A | c.4374C>T p.F1458= | Silent (SNP) | VAF 23/77 reads (30%) | catalogued as COSV51810931; called by muse, mutect2, varscan2
- SLC35G5 | c.279C>T p.P93= | Silent (SNP) | VAF 93/292 reads (32%) | catalogued as rs370747876; called by muse, mutect2, varscan2
- SLITRK3 | c.1602G>A p.L534= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as rs760985767, COSV53848875; called by muse, mutect2, varscan2
- SORL1 | c.1836C>T p.I612= | Silent (SNP) | VAF 46/68 reads (68%) | catalogued as COSV52755164; called by muse, mutect2, varscan2
- SPDEF | c.114C>T p.L38= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as rs760577698, COSV65000992; called by muse, mutect2, varscan2
- SPOCK1 | c.843C>T p.I281= | Silent (SNP) | VAF 59/91 reads (65%) | catalogued as COSV56448489; called by muse, mutect2, varscan2
- TBXAS1 | c.1230C>T p.F410= | Silent (SNP) | VAF 46/98 reads (47%) | catalogued as COSV54946062; called by muse, mutect2, varscan2
- USH2A | c.6406C>T p.L2136= | Silent (SNP) | VAF 47/73 reads (64%) | catalogued as rs1402193588, COSV56375027; called by muse, mutect2, varscan2
- ZNF135 | c.1248G>A p.G416= (on ENST00000313434 / NM_001289401.2; = p.G428= on NM_003436.4) | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV57882575; called by muse, mutect2, varscan2
- ZNF500 | c.660C>T p.S220= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV54788318; called by muse, mutect2, varscan2
- ZNF626 | c.126C>T p.F42= | Silent (SNP) | VAF 38/77 reads (49%) | catalogued as COSV52481335; called by muse, mutect2, varscan2
- ZSWIM4 | c.540C>T p.H180= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV54322162; called by muse, mutect2, varscan2
- CR1 | c.487+12137G>A | Intron (SNP) | VAF 51/271 reads (19%) | catalogued as COSV100887865; called by muse, mutect2, varscan2
- GPR26 | c.*2G>A | 3'UTR (SNP) | VAF 21/26 reads (81%) | catalogued as COSV99501017; called by muse, mutect2, varscan2
- MGAM | c.4618+128G>A | Intron (SNP) | VAF 56/104 reads (54%) | catalogued as COSV101527615; called by muse, mutect2, varscan2
- MIR520A | n.77C>T | RNA (SNP) | VAF 27/88 reads (31%) | catalogued as rs374425773; called by muse, mutect2, varscan2
- NACA | c.70+3827C>T | Intron (SNP) | VAF 23/46 reads (50%) | catalogued as rs756960195, COSV100771492; called by muse, mutect2, varscan2
- PIK3C2B | c.*154G>A | 3'UTR (SNP) | VAF 56/85 reads (66%) | catalogued as COSV100916183; called by muse, mutect2, varscan2
- RMDN2 | c.452+21677T>C | Intron (SNP) | VAF 19/59 reads (32%) | catalogued as COSV52225401; called by muse, mutect2, varscan2
- TTN | c.10360+1444G>A | Intron (SNP) | VAF 24/76 reads (32%) | catalogued as COSV100622464; called by muse, mutect2, varscan2
- ZNF99 | c.4-616G>A | Intron (SNP) | VAF 17/52 reads (33%) | catalogued as COSV68055767; called by muse, mutect2, varscan2
